Somatic mutation profile of tumor specimen TARGET-10-PANSTA-09A (aliquot TARGET-10-PANSTA-09A-01D) from TARGET case TARGET-10-PANSTA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (884 days).
Specimen TARGET-10-PANSTA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b998d17e-2db6-48b6-896e-9757c9a08542.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANSTA-14A (Bone Marrow Normal), aliquot TARGET-10-PANSTA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/737f2059-5097-439c-a7fb-7f7d329a6ed3

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 4, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6AP1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.636); catalogued as rs782690014; called by muse, mutect2, varscan2
- OTOG | c.8072G>A p.R2691H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); catalogued as rs766229978, COSV61132507; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLXNB3 | c.3446G>A p.R1149H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs781889794; called by muse, mutect2, varscan2
- SDK1 | c.5350G>A p.A1784T | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761076885, COSV67355271; called by muse, mutect2, varscan2
- ZNF831 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs143620250, COSV100926147; called by muse, mutect2, varscan2
- LCAT | c.1111_1112insGGGC p.T371Rfs*71 | Frame Shift Ins (INS) | VAF 26/56 reads (46%) | called by mutect2, pindel, varscan2
- PCDHAC1 | c.2290T>C p.S764P | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SSC5D | c.1748G>A p.S583N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AP3M1 | c.*72A>G | 3'UTR (SNP) | VAF 58/156 reads (37%) | called by muse, mutect2, varscan2
- ATF7 | c.297+79T>C | Intron (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- ATPAF2 | c.617-111G>A | Intron (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- HMGCR | c.1189+16C>G | Intron (SNP) | VAF 39/92 reads (42%) | catalogued as rs1321640086; called by muse, mutect2, varscan2
- TMX4 | c.176+406T>C | Intron (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
